MMRF case MMRF_1574 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9596f35b-f8d9-4232-9309-9c90371c208f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.9 years (24,085 days); ISS stage: I; Days to last known disease status: 1,206 days (3.3 years); Days to last follow up: 1,206 days (3.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 221 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 32 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 32 days; Days to treatment end: 221 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 246 days; Days to treatment end: 246 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 248 days; Days to treatment end: 248 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 569 days (1.6 years); Days to treatment end: 723 days (2.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 723 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 1.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 30.3 g/L; Immunoglobulin A 0.471 g/L; Immunoglobulin M 0.199 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.5 mmol/L; Albumin 39 g/L; Total Protein 8.2 g/dL; Glucose 5.67 mmol/L; C-Reactive Protein 0.27 mg/dL.
- Day 106 (ECOG 1): M Protein 0.773 g/dL; Immunoglobulin G 17.4 g/L; Immunoglobulin A 0.668 g/L; Immunoglobulin M 0.414 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 518 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Glucose 6.82 mmol/L.
- Day 221 (ECOG 1): M Protein 0.456 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.48 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 9.46 mmol/L.
- Day 270 (ECOG 1): M Protein 0.587 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.64 g/L; Hemoglobin 5.64 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.02 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 5.67 mmol/L.
- Day 368 (ECOG 1): M Protein 6.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.329 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.985 mg/dL; Immunoglobulin G 9.17 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.39 mmol/L.
- Day 436 (ECOG 1): M Protein 0.0552 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.785 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 8.69 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.94 mmol/L.
- Day 562 (ECOG 1): M Protein 0.0142 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.884 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 9.76 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 7.65 mmol/L.
- Day 653 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.78 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 134 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 6.44 mmol/L.
- Day 723 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.41 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.65 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.94 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.67 mmol/L.
- Day 814 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.24 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 1.53 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 6.38 mmol/L.
- Day 940 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 6.05 mmol/L.
- Day 1,031 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 6.55 mmol/L.
- Day 1,129 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 1.56 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 8.69 mmol/L.
- Day 1,206 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.31 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.66 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 6.88 mmol/L.

Other clinical attributes
- Day -6: Weight: 114 kg; Height: 178 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1574_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1574_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
